Surgical pathology report (de-identified scan), TCGA case TCGA-23-1109, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1109-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

PATIENT: [REDACTED]

Hospital No.: [REDACTED]

Date of Birth: [REDACTED]

Soc. Sec. No.: [REDACTED]

Location: [REDACTED]

[REDACTED]

[REDACTED]

=====

DIAGNOSIS:

1. ILEUM, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
2. SIDEWALL, RIGHT, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
3. OVARY, RIGHT, OOPHORECTOMY AND FROZEN SECTION #1:
-High-grade mullerian-derived adenocarcinoma
4. APPENDIX, APPENDECTOMY:
-High-grade mullerian-derived adenocarcinoma, metastatic
5. OVARY, LEFT, OOPHORECTOMY:
-High-grade mullerian-derived adenocarcinoma
-Fallopian tube wall is not involved with the tumor
-Paratubal soft tissue and serosa with metastatic high-grade mullerian-derived adenocarcinoma
6. OVARY, RIGHT, OOPHORECTOMY:
-High-grade mullerian-derived adenocarcinoma
-Fallopian tube is not involved with the tumor
-Paratubal soft tissue with metastatic high-grade mullerian-derived adenocarcinoma
7. RIGHT GUTTER, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
8. CUL-DE-SAC, BIOPSY:
-High-grade mullerian derived adenocarcinoma, metastatic
9. SIGMOID COLON, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
10. PERITONEUM, LEFT, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
11. SIDEWALL, LEFT, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
- [REDACTED]

[page 2 of 5]
12. PRESACRAL REGION, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
13. COLON, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
14. OMENTUM, PARTIAL OMENTECTOMY:
-High-grade mullerian-derived adenocarcinoma, metastatic
15. DIAPHRAGM, RIGHT, BIOPSY:
-Fragments of dense fibrous and calcified tissue
-Negative for malignancy
16. SMALL BOWEL MESENTERY, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic
17. RETROPERITONEUM, RIGHT, BIOPSY:
-High-grade mullerian-derived adenocarcinoma
18. EPIPLOICUM, BIOPSY:
-High-grade mullerian-derived adenocarcinoma
19. SIGMOID COLON, BIOPSY:
-High-grade mullerian-derived adenocarcinoma, metastatic

COMMENT: The tumor represents a high-grade mullerian-derived adenocarcinoma, papillary serous type, nuclear grade III, FIGO stage IV.

=====

HISTORY: Pelvic mass

MICROSCOPIC:
See Diagnosis.

GROSS:

1: ILEO TUMOR

Labeled "ileal tumor" is a 2.6 x 1.2 x 0.7 cm aggregate of soft, tan-brown, friable tissue fragments.

A. All embedded - Multiple

2: RIGHT SIDE WALL

Labeled "right side wall" and received in formalin is a 0.7 x 0.5 x 0.5 cm firm, tan-white, nodular portion of tissue.

B. All embedded - 1

3: RIGHT OVARY, FROZEN SECTION NO. 1

Labeled "right ovary, frozen section #1", received fresh in the Operating Room and subsequently fixed in formalin, is a 2.1 x 1.7 x 0.8 cm aggregate of irregular, friable, tan-white tissue fragments. No residual ovarian parenchyma is identified. A portion is submitted for frozen section microscopy. All embedded.

C. Frozen section control - 1

D. Remainder of formalin-fixed tissue fragments - Multiple

4: APPENDIX

Labeled "appendix" and received in formalin is a 9.1 x 1.8 x 1.4 cm markedly enlarged and distorted appendix with abundant attached, focally hemorrhagic, indurated mesoappendix. The serosa is tan-red to white and roughened with abundant adherent blood clot and papillary tissue fragments. On sectioning, the lumen varies from

[page 3 of 5]
0.5 cm down to complete luminal obliteration. The wall thickness varies from 0.3 cm up to a markedly thickened wall which is almost entirely replaced by tumor measuring up to 1.7 cm. An area of perforation is identified.

E. Representative section - 1

5: LEFT OVARY

Labeled "left ovary" and received in formalin is a 6.1 x 5.1 x 3.5 cm irregular, firm portion of papillary tan-white tissue fragments. No ovarian parenchyma is identified. Adjacent to this portion of tissue is an 8.1 x 0.6 x 0.6 cm segment of fimbriated fallopian tube. On sectioning, the fallopian tube lumen is focally invaded by this friable tumor mass. Representative sections submitted.

F. Friable tumor mass - 1

G. Fallopian tube cross-section - 2

6: RIGHT OVARY

Labeled "right ovary" and received in formalin is an 1.1 x 8.5 x 2.7 cm ovary which is entirely replaced by friable tan-white tissue fragments. No residual ovarian parenchyma is identified. On section, there are multiple clear fluid-filled serous cysts. Minimal residual ovarian parenchyma is identified overlying some of these cysts. On sectioning, there is a 2.0 x 0.5 x 0.5 cm length of non-fimbriated fallopian tube with a hemorrhagic, red serosa. On section, the fallopian tube lumen is involved by tumor. Representative sections submitted.

H. Papillary tumor mass - 1

I. Thin-walled cystic area - 2

J. Fallopian tube - 2

7: RIGHT GUTTER

Labeled "right gutter" and received in formalin is a 3.5 x 8.2 x 4.9 cm irregular, firm portion of fibromembranous fibroadipose tissue which is almost entirely replaced by papillary tan white tumor fragments.

K. Representative section - 1

8: CUL DE SAC TUMOR

Labeled "cul-de-sac tumor" and received in formalin is an 8.2 x 5.3 x 2.2 cm irregular, firm portion of friable tan-white tumor.

L. Representative section - 1

9: SIGMOID TUMOR

Labeled "sigmoid tumor" and received in formalin is a 4.1 x 2.2 x 1.7 cm aggregate of irregular, firm, tan-white, papillary tumor fragments.

M. Representative section - 1

10: LEFT PERITONEAL TUMOR

Labeled "left peritoneal tumor" and received in formalin is a 3.3 x 2.4 x 1.8 cm aggregate of irregular, firm, pink and white papillary tumor fragments.

N. Representative sections - 2

11: LEFT SIDE WALL

Labeled "left sidewall" and received in formalin is a 3.4 x 2.7 x

[page 4 of 5]
1.4 cm aggregate of irregular, firm, tan-white papillary tumor fragments.

O. Representative sections - 2

12: PRE SACRAL TUMOR

Labeled "presacral tumor" and received in formalin are four irregular, firm, granular, tan-black fragments of tissue ranging from 0.4 x 0.3 x 0.2 cm up to 1.1 x 0.4 x 0.2 cm.

P. All embedded - 4

13: RIGHT COLON

Labeled "right colon" and received in formalin is a 2.3 x 2.1 x 1.7 cm firm, tan-white, friable, polypoid fragment of tumor.

Q. Representative section - 1

14: OMENTUM

Labeled "omentum" and received in formalin is a 15.0 x 13.0 x 6.0 cm portion of yellow lobulated omentum. There is a 2.0 x 1.0 x 0.6 cm well-circumscribed, firm, tan-white nodule which on sectioning contains abundant fibropapillary tumor fragments.

R. Representative section - 1

15: RIGHT DIAPHRAGM TUMOR

Labeled "right diaphragm tumor" and received in formalin is a 6.2 x 4.9 x 3.7 cm irregular, firm, lobular portion of tissue with a moderate amount of attached fat. On sectioning, cut surface consists of abundant friable, papillary tumor.

S. Representative section - 1

16: SMALL BOWEL MESENTERY

Labeled "small bowel mesentery" and received in formalin is a 1.6 x 1.4 x 0.7 cm aggregate of irregular, firm, yellow fragments of

focally calcified tissue which contain minimal friable, yellow grumous material.

T. Representative sections - 2

17: RIGHT RETROPERITONEAL TUMOR

Labeled "right retroperitoneal tumor" and received in formalin is a 3.7 x 3.4 x 3.2 cm aggregate of irregular friable tan-white tissue fragments.

U. Representative section - 1

18: EPIIPLOICUM

Labeled "epiploicum" and received in formalin is a 0.7 x 0.6 x 0.6 cm well-circumscribed, firm, tan-red appendix epiploica. On sectioning, specimen is almost entirely replaced by firm, tan-white, papillary tumor mass.

V. All embedded, bisected - 2

19: SIGMOID COLON

Labeled "sigmoid colon" and received in formalin is a 1.4 x 1.4 x 1.2 cm firm, tan-white, nodular portion of tissue and blood clot. On sectioning, the nodules consist of firm tan-white tumor mass.

W. Representative sections - 2

[page 5 of 5]
[REDACTED]

[REDACTED]

OPERATIVE CONSULT (FROZEN):

#1: -High-grade mullerian-derived adenocarcinoma
-Sterile tissue saved for clonogenic studies

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Confidentiality Warning: The information in this system should only be viewed by patient care personnel with a "need to know" for purposes of diagnosis and treatment. All accesses are logged with your name, the patient name, the type of data viewed, the date and time. Inappropriate accesses are subject to disciplinary measures and/or legal action, up to and including termination of employment on the first offense.

Source: NCI Genomic Data Commons file f9efd368-c1f6-4a96-a276-2a684b78e25d (TCGA-23-1109.D70D81CA-5EB2-426C-AFC7-4D52BC36BFB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).